Somatic mutation profile of tumor specimen TCGA-17-Z017-01A (aliquot TCGA-17-Z017-01A-01W-0746-08) from TCGA case TCGA-17-Z017, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15daffdc-dd31-4527-abc8-0e62168e0ebd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z017-11A (Solid Tissue Normal), aliquot TCGA-17-Z017-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e9ceaa9-c20f-45a1-a55e-7ef515c0b15d

The open-access MAF lists 234 somatic variants for this specimen: 184 protein-altering or splice-affecting, 44 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 44, Nonsense Mutation 9, Splice Site 4, Frame Shift Del 3, RNA 2, Intron 2, Splice Region 1, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1057519995, COSV52663197, COSV52713501, COSV52816344; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.1610C>A p.A537D | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.104); catalogued as COSV56892367; called by muse, mutect2, varscan2
- ADGRL2 | c.2846G>T p.R949M (on ENST00000370717 / NM_001366005.1; = p.R936M on NM_012302.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54683299; called by muse, mutect2, varscan2
- AKR7A2 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1307632574; called by muse, mutect2, varscan2
- AP1G1 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as rs1216363126; called by muse, mutect2, varscan2
- AP4E1 | c.3182C>G p.S1061C | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55916756; called by muse, mutect2, varscan2
- CBL | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880432, COSV50663321; called by mutect2, varscan2
- CCNG1 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as rs1234028837, COSV57084381; called by muse, mutect2, varscan2
- CEMIP2 | c.3534del p.S1179Qfs*81 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | catalogued as COSV65487935; called by mutect2, pindel, varscan2
- CEP170 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1479637146; called by muse, mutect2, varscan2
- CLCN4 | c.2076G>T p.K692N | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs900821812; called by muse, mutect2, varscan2
- COL9A1 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1252306405; called by muse, mutect2, varscan2
- CRX | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.264); catalogued as CM153054; called by muse, mutect2, varscan2
- CSMD1 | c.5263G>T p.G1755C (on ENST00000520002; = p.G1754C on NM_033225.6) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59279370, COSV59350430; called by muse, mutect2, varscan2
- DDX60L | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.169); catalogued as rs370061220; called by muse, mutect2, varscan2
- ELAVL4 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs116030028; called by mutect2, varscan2
- EPHA7 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV65186253; called by muse, mutect2, varscan2
- F11R | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.797); catalogued as COSV57039722; called by muse, mutect2, varscan2
- FAM47A | c.1033C>A p.R345S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.307); catalogued as COSV60495012, COSV60495976; called by muse, mutect2, varscan2
- FAM47A | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as COSV60495125; called by muse, mutect2, varscan2
- FBN2 | c.2679C>G p.S893R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs778473524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD1 | c.2647C>G p.R883G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV64309122; called by muse, mutect2, varscan2
- FLG | c.1662G>T p.R554S | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as rs760876767; called by muse, mutect2, varscan2
- FRMPD3 | c.4397C>G p.P1466R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as rs1424913158; called by muse, mutect2, varscan2
- GOLGA4 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs141780526; called by muse, mutect2, varscan2
- GUCY2D | c.2600C>A p.T867K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs375727197; called by muse, mutect2, varscan2
- HRG | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs1434562813; called by muse, mutect2, varscan2
- IGSF1 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.57); catalogued as COSV63837746; called by muse, mutect2, varscan2
- IGSF21 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52129635; called by muse, mutect2, varscan2
- KDR | c.2591C>A p.T864K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55769829; called by muse, mutect2, varscan2
- KRTAP15-1 | c.250T>A p.C84S | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61877727; called by muse, mutect2, varscan2
- LAIR1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs772363393; called by muse, mutect2, varscan2
- LIG3 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as COSV52008788; called by muse, mutect2, varscan2
- LILRA2 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99252585; called by muse, mutect2, varscan2
- LRFN5 | c.1426C>A p.L476M | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53244066; called by mutect2, varscan2
- MAGEA6 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61448888; called by muse, mutect2, varscan2
- MAGI3 | c.4385G>A p.W1462* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs370236916; called by muse, mutect2, varscan2
- MROH2B | c.2827C>G p.L943V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV68182761; called by muse, mutect2, varscan2
- MYH4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs755708452, COSV55113074; called by muse, mutect2, varscan2
- MYH6 | c.2489C>A p.P830H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM052256; called by muse, mutect2, varscan2
- NELL1 | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.197); catalogued as COSV54334539; called by muse, mutect2
- NRXN3 | c.2362C>T p.L788F (on ENST00000335750 / NM_001330195.2; = p.L415F on NM_004796.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as rs1290891540; called by muse, mutect2, varscan2
- OR2T3 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 65/624 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV100613331; called by muse, mutect2, varscan2
- OR51B5 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56177087; called by muse, mutect2, varscan2
- OR5P2 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV61490151; called by muse, mutect2, varscan2
- OR5R1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100393397; called by muse, mutect2, varscan2
- OR6K2 | c.757T>A p.F253I | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100656799; called by muse, mutect2, varscan2
- PAX2 | c.890C>A p.T297N (on ENST00000428433 / NM_003987.5; = p.T274N on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1411259285; called by muse, mutect2, varscan2
- PCDH19 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55271776; called by muse, mutect2, varscan2
- PCDHB11 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.053); catalogued as COSV53376237, COSV99503576; called by muse, varscan2
- PCDHB7 | c.2036A>T p.D679V | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV50776345; called by muse, mutect2
- PCDHB7 | c.2257C>A p.L753M | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV50754596; called by muse, mutect2
- PDZD7 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100931698; called by muse, mutect2, varscan2
- PKHD1 | c.10726T>A p.W3576R | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV64382554; called by muse, mutect2, varscan2
- PRKCG | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV104374180; called by muse, mutect2, varscan2
- PSG6 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1486709671; called by muse, mutect2, varscan2
- PSMD3 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52859298; called by muse, mutect2, varscan2
- PTCHD4 | c.1651G>T p.V551L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1399219388; called by muse, mutect2, varscan2
- PUM3 | c.1264A>G p.I422V | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs565664019; called by muse, mutect2, varscan2
- RASSF2 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65081912; called by muse, mutect2, varscan2
- ROCK1 | c.362dup p.W122Lfs*25 | Frame Shift Ins (INS) | VAF 30/113 reads (27%) | catalogued as rs35810558; called by mutect2, pindel, varscan2
- ROR2 | c.2362G>T p.G788W | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV65217629; called by muse, mutect2, varscan2
- SCN3A | c.3494C>A p.P1165Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563038965; called by muse, mutect2, varscan2
- SPIN4 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100633365; called by muse, mutect2, varscan2
- STYK1 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50012710; called by muse, varscan2
- SYF2 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52573217; called by muse, mutect2, varscan2
- TAS2R1 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV66779521; called by muse, mutect2, varscan2
- TMEM260 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs760102891; called by muse, mutect2, varscan2
- ZSCAN1 | c.371-1G>C p.X124_splice | Splice Site (SNP) | VAF 7/59 reads (12%) | catalogued as rs776182361, COSV99991979; called by muse, mutect2, varscan2
- ABCB5 | c.3103G>T p.G1035C (on ENST00000404938 / NM_001163941.2; = p.G590C on NM_178559.6) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ABI3BP | c.1345A>T p.T449S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACAN | c.2695C>G p.L899V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ACBD5 | c.548A>T p.N183I (on ENST00000375888 / NM_001352568.1; = p.N174I on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ACTRT1 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 111/439 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADD3 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, varscan2
- AGAP4 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AQR | c.1328A>T p.Y443F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF6 | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ATM | c.5511T>G p.F1837L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- AVL9 | c.1318C>A p.Q440K | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BHMT2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BNC1 | c.2479A>G p.M827V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BPTF | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CAPN10 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163L1 | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 80/349 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD34 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CLCA4 | c.1884T>A p.N628K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLMN | c.325-2A>T p.X109_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- COL24A1 | c.3628-1G>A p.X1210_splice | Splice Site (SNP) | VAF 47/243 reads (19%) | called by muse, mutect2, varscan2
- CPA3 | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCUN1D3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLGAP1 | c.603G>C p.W201C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- DNMT3B | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- DSC3 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DSG3 | c.49-2A>T p.X17_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- FAM155B | c.506del p.P169Lfs*56 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- FLNB | c.2450G>C p.G817A | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FN1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- FYB1 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- GART | c.2608A>T p.N870Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by mutect2, varscan2
- GRIN2B | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRK4 | c.204G>T p.R68S (on ENST00000398052 / NM_182982.3; = p.R36S on NM_005307.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXB1 | c.866G>T p.C289F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- IGKV1-12 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 163/686 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV3D-20 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- IL12RB2 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- IL13RA2 | c.601T>A p.Y201N | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IPP | c.1511A>G p.E504G | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IPP | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- IQGAP3 | c.3940G>T p.D1314Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KATNIP | c.4516G>C p.A1506P | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- KCNA2 | c.566G>C p.R189P | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- KCNH1 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- KIAA0232 | c.3824T>C p.I1275T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL13 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDLRAD4 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LGALS13 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAGEA6 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAN1A2 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MAP10 | c.2109G>C p.K703N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAPKAPK2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MMP21 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.548); called by muse, mutect2
- MORC4 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTCL1 | c.4389G>T p.E1463D (on ENST00000306329 / NM_001378206.1; = p.E1144D on NM_015210.4) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTMR6 | c.610A>T p.S204C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAGA | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- NET1 | c.1478T>G p.F493C (on ENST00000355029 / NM_001047160.3; = p.F439C on NM_005863.5) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NETO1 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR13C3 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- OR4N5 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 81/343 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- OR5I1 | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR8U1 | c.647T>A p.V216D | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- PABPC5 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH11X | c.3667C>T p.P1223S | Missense Mutation (SNP) | VAF 78/374 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- PCDH11X | c.3683C>A p.A1228D | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.601); called by muse, varscan2
- PCDHB7 | c.1517T>A p.I506N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGA3 | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- PCDHGA7 | c.1933G>T p.A645S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PCDHGB3 | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCL3 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.022); called by muse, varscan2
- PDIA4 | c.1343A>T p.E448V (on ENST00000286091 / NM_001371244.1; = p.E447V on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- POLR2M | c.972A>T p.Q324H | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- PORCN | c.1173G>C p.L391F (on ENST00000326194 / NM_203475.3; = p.L380F on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by mutect2, varscan2
- PPARGC1A | c.1273T>A p.S425T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPFIA4 | c.2861C>T p.P954L (on ENST00000447715; = p.P955L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PRSS58 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PTPRE | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RHOH | c.308G>C p.R103T | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RSRC1 | c.457A>T p.K153* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- RYR2 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SCML2 | c.1754T>A p.L585Q | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMA3A | c.1856A>T p.E619V | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHOC2 | c.321A>T p.L107F | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A19 | c.1102A>C p.N368H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- SLC6A8 | c.603C>G p.D201E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SMARCA4 | c.1802del p.P601Rfs*12 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel
- SNRPD1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- SPAG17 | c.4019C>A p.S1340Y | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- SPATA31A3 | c.2791C>G p.L931V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.112); called by mutect2, varscan2
- SPTB | c.5334G>T p.M1778I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STRA6 | c.1812C>A p.D604E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- STYXL2 | c.1788C>A p.H596Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SV2B | c.1719G>T p.M573I | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- TAF1L | c.5120G>C p.G1707A | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TECRL | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- THOC2 | c.3497C>G p.A1166G | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THRAP3 | c.1045C>G p.L349V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TMC5 | c.2693A>G p.Y898C (on ENST00000396229 / NM_001105248.1; = p.Y652C on NM_024780.5) | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM131 | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNNT2 | c.232A>G p.R78G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TP53TG5 | c.271A>T p.N91Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAPPC5 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM33 | c.2194G>T p.G732C | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM33 | c.2193A>T p.S731= | Splice Region (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
- USH2A | c.5204G>T p.G1735V | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- VCAN | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK3 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWC3 | c.3214G>C p.E1072Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.5375T>C p.V1792A (on ENST00000628543; = p.V1967A on NM_152381.6) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF7 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB41 | c.665T>A p.L222* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- ZSCAN5B | c.581G>T p.R194M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); called by muse, varscan2
- AKAP6 | c.3915G>T p.L1305= | Silent (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- ATG2B | c.5172A>T p.T1724= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- ATP4A | c.1101C>T p.C367= | Silent (SNP) | VAF 92/751 reads (12%) | catalogued as rs766064812, COSV52872003; called by muse, mutect2, varscan2
- BRCA2 | c.819A>T p.S273= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- CLEC4A | c.369A>G p.E123= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs761771589; called by muse, mutect2, varscan2
- CPA1 | c.99G>A p.E33= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- CSMD2 | c.696C>A p.I232= | Silent (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- DCHS1 | c.6696A>T p.T2232= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- DNAH17 | c.5118C>G p.T1706= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101103295; called by muse, mutect2, varscan2
- DYNC1H1 | c.11343C>T p.T3781= | Silent (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- DZIP3 | c.504C>A p.I168= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs140722866; called by muse, mutect2, varscan2
- EMP3 | c.132G>T p.T44= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs139549534; called by mutect2, varscan2
- ETV7 | c.849G>C p.L283= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as COSV60316261; called by muse, mutect2, varscan2
- FAM155B | c.1191G>A p.Q397= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1351879795; called by muse, mutect2, varscan2
- GTPBP2 | c.630C>T p.R210= | Silent (SNP) | VAF 98/206 reads (48%) | catalogued as rs1304006378; called by muse, mutect2, varscan2
- HK3 | c.1977C>T p.A659= | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- ITK | c.66T>C p.S22= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- KRT4 | c.492C>A p.V164= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99542500; called by muse, mutect2, varscan2
- MAPK8IP1 | c.873C>T p.D291= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs138625751; called by muse, mutect2, varscan2
- NFATC4 | c.627T>C p.F209= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- NHLH2 | c.312G>T p.L104= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- OR6V1 | c.213A>T p.V71= | Silent (SNP) | VAF 82/445 reads (18%) | called by muse, mutect2, varscan2
- OR8G5 | c.9A>G p.A3= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- PAPPA2 | c.840T>A p.A280= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- PCDH11X | c.1776C>A p.I592= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- PTPRD | c.535C>A p.R179= | Silent (SNP) | VAF 44/265 reads (17%) | catalogued as COSV61934311, COSV61944518; called by muse, mutect2, varscan2
- RBM10 | c.954G>T p.G318= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- RIPPLY1 | c.189C>A p.S63= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- RTL3 | c.18A>T p.A6= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- SALL1 | c.1788G>C p.G596= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- SATL1 | c.30C>T p.G10= (on ENST00000395409; = p.G197= on NM_001012980.2) | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV60575403; called by muse, mutect2, varscan2
- SIGLEC10 | c.1119C>A p.G373= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV59480400; called by muse, mutect2, varscan2
- SSH2 | c.438C>T p.S146= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs1265531111, COSV52178657; called by muse, mutect2, varscan2
- TAB3 | c.732T>C p.T244= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- TCN1 | c.1140C>A p.R380= | Silent (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- TDRD5 | c.2295C>T p.S765= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs763691989; called by muse, mutect2, varscan2
- TG | c.2877G>A p.V959= | Silent (SNP) | VAF 82/230 reads (36%) | catalogued as COSV55098325; called by muse, mutect2, varscan2
- TRAT1 | c.513C>T p.P171= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs765082707; called by muse, mutect2, varscan2
- TRPC1 | c.867G>T p.T289= (on ENST00000476941 / NM_001251845.2; = p.T255= on NM_003304.4) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV56423115; called by muse, mutect2, varscan2
- TRPM2 | c.321C>G p.T107= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100309535, COSV55974764; called by muse, mutect2
- UFSP2 | c.210C>A p.T70= | Silent (SNP) | VAF 25/118 reads (21%) | called by muse, mutect2, varscan2
- WDR44 | c.1860T>C p.F620= | Silent (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- ZFPM2 | c.45G>T p.P15= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV101343524, COSV68274572; called by muse, mutect2, varscan2
- ZSCAN5B | c.1059G>C p.P353= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- EMC3-AS1 | chr3:10007551 G>T | 3'Flank (SNP) | VAF 29/104 reads (28%) | catalogued as rs775439348; called by muse, mutect2, varscan2
- MIR544A | n.14A>G | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- MIR770 | n.87G>T | RNA (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185147G>T | Intron (SNP) | VAF 97/419 reads (23%) | catalogued as rs745333470; called by muse, mutect2, varscan2
- REG3G | c.*1G>T | 3'UTR (SNP) | VAF 34/67 reads (51%) | catalogued as COSV99709278; called by muse, mutect2, varscan2
- THRA | c.1110+41G>T | Intron (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99225776; called by muse, mutect2
